Gene-level copy-number profile of tumor specimen TCGA-WE-A8ZT-06A from TCGA case TCGA-WE-A8ZT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 25.7 years (9,389 days).
Specimen TCGA-WE-A8ZT-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.7a553fc4-e7f3-45ad-807e-61a4838876d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WE-A8ZT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0df7ccfd-67d3-42fa-a7b3-baa43257fa31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,639; copy number 2: 54,327; copy number 3: 2,512; copy number 4: 176; copy number 6: 165.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WE-A8ZT-06A-11D-A371-01): tumor purity 0.81, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 165 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:2,227,803–5,260,950, 85 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:5,609,227–9,294,133, 59 genes, copy number 6 (within-gene range 4–6): HNRNPA1P37, AL022097.1, AL136968.2, AL136968.1, AL136307.1, RN7SL221P, PKMP5, NRN1, F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1.
- chr6:12,514,110–14,006,901, 21 genes, copy number 6: RPL15P3, LINC02530, PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1.

Autosomal genes at a single copy (total copy number 1): 1,730. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
